Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7606, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7606-01A (Primary Tumor).

Tumor: [REDACTED]
Normal: [REDACTED]
Slide: [REDACTED]

Microscopic Description:

1. Sections demonstrate mildly hypercellular white matter that is infiltrated by mildly to moderately atypical fibrillary astrocytes. No mitotic figures are seen. There is no microvascular proliferation or necrosis.
2. Sections demonstrate gray matter with only a rare, mildly atypical cell scattered throughout. These likely represent infiltrating tumor cells.
3. Sections demonstrate gray and white matter. The gray matter demonstrates little involvement with tumor. The white matter is mildly hypercellular due to diffuse tumor infiltration as described in specimen #1.

Diagnosis:

Positive for infiltrating astrocytoma.

Source: NCI Genomic Data Commons file 0fe73939-7f97-456f-9bb3-9f9233402bab (TCGA-HT-7606.4F988B76-FC06-45AF-A537-A90D72713A70.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).